Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84L, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84L-01A (Primary Tumor).

Patient Results

All results - Performed since

At least 1 Final Result

LAB. NO.

DOCTOR :
WARD :
REQUEST DATE :
DATE RECEIVED :
CONSULTANT :

D.O.B. :

SPECIMEN:

- A. Left temporal brain tumour.
- B. Left temporal brain tumour.

CLINICAL :

Seizure. Non-enhancing lesion on MRI. ?Low grade glioma.

MACROSCOPIC:

- A. Two fragments of tan tissue each 4 x 5mm. (Two imprints and frozen section prepared)

INTRA-OPERATIVE ASSESSMENT - FROZEN SECTION

Normal brain tissue together with some fragments showing mild gliosis. A few atypical astrocytes noted - inconclusive. Cannot exclude a low grade astrocytoma or DNET or other. Requested more tissue.

BLOCK KEY: 1:remaining tissue from frozen section

- B. Multiple fragments of cream coloured brain tissue, the largest fragment measuring 33mm in greatest extent.

BLOCK KEY: 1-5:brain tissue

MICROSCOPIC:

A. and B. Specimens A and B will be described together as they show similar findings. Sections show brain tissue, and include both normal grey and white matter. There are large areas involving both grey and white matter of hypercellularity that contain cells possessing moderate sized, rounded, irregular nuclei with moderately coarse chromatin. Many of these cells show cytoplasmic retraction and a "fried egg" appearance. There are also occasional cells with large, hyperchromatic and irregular nuclei that are often "naked" in appearance. No necrosis or mitotic figures are evident. Some of the tumour cells stain positively for p53.

Cytogenetic FISH analysis has been performed and there was no loss of 1p or 19q and EGFR amplification was not detected.

CONCLUSION:

A. and B. Left temporal brain tumour: Low grade (WHO grade II) diffuse glioma favoured to represent a mixed oligoastrocytoma (see comment).

COMMENT:

The differential diagnosis includes an oligodendroglioma (WHO grade II) but this is considered less likely as there is some positivity for p53 and the cytogenetic FISH studies did not show a loss of 1p or 19q.

REGISTRAR:

PATHOLOGIST:

DOCTOR REVIEWING:

DATED:

ICD-O-3
Oligoastrocytoma, grade II 9382/3
Site: Brain, supratentorial NOS C71.0
① Brain, temporal lobe C71.2
JW 10/30/13

Requested by:

Source: NCI Genomic Data Commons file b0e5efbe-7112-422a-8412-25a81e8b4afb (TCGA-TM-A84L.731D979A-5A35-47BE-AA7E-83EB1CF8857F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).